Somatic mutation profile of tumor specimen C3N-01757-04 (aliquot CPT0163240006) from CPTAC case C3N-01757, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 64.4 years (23,506 days).
Specimen C3N-01757-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f782a240-4259-482d-8795-cdf666684553.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01757-31 (Blood Derived Normal), aliquot CPT0163310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f90ed80a-e4b1-4709-b943-db6a46b98fc5

The open-access MAF lists 180 somatic variants for this specimen: 110 protein-altering or splice-affecting, 39 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 39, Intron 16, Nonsense Mutation 8, RNA 7, 5'UTR 4, Splice Region 3, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 2, Splice Site 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 206/644 reads (32%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC133561.1 | n.2019C>T | Splice Region (SNP) | VAF 18/280 reads (6%) | catalogued as rs1309722800; called by muse, varscan2
- ASCC3 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as rs911548929; called by muse, mutect2, varscan2
- C9 | c.1429T>C p.Y477H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as rs1419449142; called by muse, mutect2
- CBFA2T3 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as rs899943902; called by muse, mutect2
- CHPF2 | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs143363103; called by muse, mutect2
- CRELD2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs756038625; called by muse, mutect2
- CSMD3 | c.9668G>T p.G3223V (on ENST00000297405 / NM_001363185.1; = p.G3054V on NM_052900.3) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs999320871; called by muse, mutect2
- CUX1 | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1234501114; called by muse, mutect2
- DAB2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs775183439; called by muse, mutect2
- DNM2 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs781589891, COSV100117734; called by muse, mutect2, varscan2
- DNM3 | c.1627G>A p.G543S (on ENST00000355305 / NM_001350206.2; = p.G533S on NM_015569.5) | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs570667502; called by muse, mutect2
- EBF3 | c.889G>A p.G297R (on ENST00000355311 / NM_001375392.1; = p.G288R on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62478455; called by muse, varscan2
- FAM131B | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 59/453 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1003753476; called by muse, mutect2, varscan2
- FER1L6 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206273, COSV67549437; called by muse, mutect2
- FGF16 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs781914307, COSV71546153; called by muse, mutect2, varscan2
- GAL3ST2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 74/471 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs202108971, COSV51950164; called by muse, mutect2, varscan2
- GGA3 | c.1564C>T p.L522F (on ENST00000537686 / NM_138619.4; = p.L489F on NM_014001.5) | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.708); catalogued as rs960288768; called by muse, mutect2
- HEXIM1 | c.675C>A p.Y225* | Nonsense Mutation (SNP) | VAF 31/630 reads (5%) | catalogued as COSV60177640; called by muse, mutect2
- INPP5F | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs760565175; called by muse, mutect2, varscan2
- INSL3 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1423902478, COSV57952815; called by muse, mutect2
- NOC4L | c.1320C>T p.A440= | Splice Region (SNP) | VAF 29/177 reads (16%) | catalogued as rs771941255; called by muse, mutect2, varscan2
- OR5K2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101415997; called by muse, mutect2, varscan2
- OR8K3 | c.536G>C p.C179S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs752339604; called by muse, mutect2
- OTUD4 | c.830C>T p.S277F (on ENST00000447906 / NM_001366057.1; = p.S212F on NM_001102653.1) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99031040; called by muse, mutect2, varscan2
- PAPPA2 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.908); catalogued as COSV62774924; called by muse, mutect2, varscan2
- PHTF1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs917043534, COSV63369300; called by muse, mutect2
- PIK3CG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV63246379; called by muse, mutect2, varscan2
- PKD1L1 | c.4247G>A p.R1416K | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as rs1476665767; called by muse, mutect2, varscan2
- PREX2 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55775722; called by muse, mutect2
- PTPRQ | c.3787G>A p.A1263T (on ENST00000616559; = p.A1221T on NM_001145026.2) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs779625975; called by muse, mutect2, varscan2
- RPS9 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100256317; called by muse, mutect2, varscan2
- SH3GL3 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745887599; called by muse, mutect2
- SLC9A4 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV54836518; called by muse, mutect2, varscan2
- USP29 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | catalogued as COSV54141542, COSV54141783; called by muse, mutect2
- ZNF33B | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV100847819; called by muse, mutect2, varscan2
- ZNF730 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV74168084; called by muse, mutect2, varscan2
- AGBL4 | c.1416G>C p.K472N | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.966); called by muse, mutect2
- AJUBA | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 25/217 reads (12%) | called by muse, mutect2, varscan2
- ANKK1 | c.2112C>A p.N704K | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ARHGEF11 | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- C16orf78 | c.243C>G p.N81K | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C19orf44 | c.1403A>G p.Y468C | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C1QTNF3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CA13 | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAD | c.5846dup p.M1949Ifs*23 | Frame Shift Ins (INS) | VAF 47/245 reads (19%) | called by mutect2, pindel, varscan2
- CCSAP | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CD99L2 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CDHR3 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.102); called by muse, mutect2
- CDK8 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COG5 | c.1756A>T p.I586L (on ENST00000347053 / NM_001379512.1; = p.I607L on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- COQ8A | c.1683dup p.A562Cfs*12 | Frame Shift Ins (INS) | VAF 16/182 reads (9%) | called by mutect2, pindel
- CPT1A | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 38/665 reads (6%) | called by muse, mutect2
- DCSTAMP | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DDA1 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2
- DNAH11 | c.8945T>C p.I2982T | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2
- EFHC1 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 47/376 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ELOA2 | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- EYS | c.7091T>A p.L2364Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.816); called by muse, mutect2
- FAT2 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 32/294 reads (11%) | called by muse, mutect2, varscan2
- FRMPD3 | c.4237G>A p.G1413S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FUS | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GFRAL | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, varscan2
- GRXCR1 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- IGHV4-28 | c.248T>A p.L83H | Missense Mutation (SNP) | VAF 36/731 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- IRF2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- KAT6B | c.3976A>G p.R1326G | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KRTAP26-1 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- LAMA5 | c.5282_5298+15del p.X1761_splice | Splice Site (DEL) | VAF 19/166 reads (11%) | called by mutect2, pindel
- LRRK2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRTM3 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MATN1 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTCL1 | c.3409C>A p.Q1137K (on ENST00000306329 / NM_001378206.1; = p.Q818K on NM_015210.4) | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NEB | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOA1 | c.196G>C p.G66R | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- NOA1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); called by muse, mutect2
- NPFFR2 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.11); called by muse, mutect2
- NUP88 | c.1836-8A>G | Splice Region (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- OR4C46 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); called by muse, mutect2
- PARD6G | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- PARP4 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- PCDH12 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDZRN4 | c.2926C>A p.Q976K (on ENST00000402685 / NM_001164595.2; = p.Q718K on NM_013377.4) | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.428); called by muse, mutect2
- PKDREJ | c.3895_3896del p.W1299Afs*9 | Frame Shift Del (DEL) | VAF 19/122 reads (16%) | called by pindel, varscan2
- PKHD1L1 | c.6862del p.L2288Wfs*10 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- PLD1 | c.3153C>A p.F1051L | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PREX2 | c.2482A>G p.T828A | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2
- RASA1 | c.2398C>T p.Q800* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2, varscan2
- RNF113B | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF186 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- RNF43 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- SHISA9 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 61/636 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- SLC25A25 | c.886A>G p.S296G | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SLX4 | c.2894G>T p.C965F | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.165); called by muse, mutect2
- SPRTN | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- SPTBN4 | c.1649G>T p.W550L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2
- SVEP1 | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- TIMM29 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- TSHZ2 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTI1 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.12253G>T p.A4085S (on ENST00000591111; = p.A4039S on NM_003319.4) | Missense Mutation (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- VPS13D | c.10818G>T p.E3606D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VPS36 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB39 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); called by muse, mutect2
- ZBTB45 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- ZFYVE9 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZMAT4 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF319 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.761); called by muse, mutect2
- ZNF568 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF732 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2
- ABCA2 | c.2535G>A p.S845= (on ENST00000614293; = p.S815= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as rs376238169, COSV55799104; called by muse, mutect2
- AGO2 | c.426G>T p.A142= | Silent (SNP) | VAF 16/312 reads (5%) | catalogued as COSV55054849; called by muse, mutect2
- AIRE | c.1311C>T p.C437= | Silent (SNP) | VAF 74/532 reads (14%) | catalogued as rs771244760; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAMSAP1 | c.3717C>T p.S1239= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as rs373341551; called by muse, mutect2
- CELSR1 | c.3882C>T p.I1294= | Silent (SNP) | VAF 26/402 reads (6%) | called by muse, mutect2
- CFHR4 | c.690G>A p.L230= (on ENST00000367416 / NM_001201551.2; = p.L231= on NM_001201550.3) | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99260248; called by muse, mutect2
- DET1 | c.414G>A p.E138= (on ENST00000268148 / NM_001144074.3; = p.E149= on NM_017996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/302 reads (14%) | catalogued as rs1376992851; called by muse, mutect2, varscan2
- DISP3 | c.714C>A p.P238= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs372733155; called by muse, mutect2, varscan2
- DNAH3 | c.10290C>A p.P3430= | Silent (SNP) | VAF 26/271 reads (10%) | called by muse, mutect2, varscan2
- ELOA2 | c.486A>G p.P162= | Silent (SNP) | VAF 57/410 reads (14%) | catalogued as rs1318139140; called by muse, mutect2, varscan2
- FAT4 | c.14406T>A p.P4802= | Silent (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- GFRA3 | c.192G>T p.L64= | Silent (SNP) | VAF 20/229 reads (9%) | called by muse, mutect2
- GJA8 | c.534G>T p.L178= | Silent (SNP) | VAF 24/376 reads (6%) | catalogued as rs1553242731; called by muse, mutect2
- KDM2A | c.3456G>T p.L1152= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs751496172; called by muse, mutect2
- LILRA2 | c.333C>A p.P111= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV99253932; called by muse, mutect2
- MAST4 | c.5862C>T p.R1954= (on ENST00000403625 / NM_001164664.2; = p.R1765= on NM_015183.3) | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- MMP17 | c.1767G>C p.L589= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- MNT | c.1128G>A p.A376= | Silent (SNP) | VAF 14/257 reads (5%) | catalogued as rs1385087163; called by muse, mutect2
- MSRB3 | c.465A>G p.K155= | Silent (SNP) | VAF 32/426 reads (8%) | called by muse, mutect2
- MYH4 | c.2517G>A p.K839= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV99701671; called by muse, mutect2
- NCOA3 | c.2940G>A p.Q980= | Silent (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2
- NF1 | c.3747T>A p.S1249= | Silent (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- OR51V1 | c.321C>A p.I107= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1758G>A p.A586= | Silent (SNP) | VAF 22/580 reads (4%) | catalogued as COSV100249919; called by muse, mutect2
- PCDHGA4 | c.1599C>T p.S533= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as COSV99535192, COSV99547627; called by muse, mutect2, varscan2
- PLEC | c.5092C>A p.R1698= (on ENST00000322810 / NM_201380.4; = p.R1588= on NM_000445.5) | Silent (SNP) | VAF 66/1202 reads (5%) | called by muse, mutect2
- RAD23A | c.906C>G p.G302= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- RASGRP1 | c.1137C>T p.N379= | Silent (SNP) | VAF 32/427 reads (7%) | catalogued as rs535554337; called by muse, mutect2
- RP1 | c.603G>T p.T201= | Silent (SNP) | VAF 18/540 reads (3%) | catalogued as rs1484711577, COSV55114043; called by muse, mutect2
- RREB1 | c.2508G>A p.A836= | Silent (SNP) | VAF 10/222 reads (5%) | catalogued as rs1323679393, COSV58564788; called by muse, mutect2
- SLC7A5 | c.15C>T p.G5= | Silent (SNP) | VAF 14/159 reads (9%) | catalogued as rs775032050; called by muse, mutect2
- SPN | c.795G>A p.L265= | Silent (SNP) | VAF 31/224 reads (14%) | called by muse, mutect2, varscan2
- SYNE2 | c.19272C>T p.D6424= | Silent (SNP) | VAF 15/236 reads (6%) | catalogued as rs774346816; called by muse, mutect2
- UBC | c.957C>T p.L319= | Silent (SNP) | VAF 129/628 reads (21%) | catalogued as rs752234660; called by muse, mutect2, varscan2
- USP39 | c.1509C>T p.I503= | Silent (SNP) | VAF 18/217 reads (8%) | catalogued as rs1300415456; called by muse, mutect2
- WDR24 | c.702G>A p.A234= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as rs1019776835; called by muse, mutect2, varscan2
- WDR97 | c.3765C>T p.L1255= | Silent (SNP) | VAF 63/380 reads (17%) | called by muse, mutect2, varscan2
- ZNF142 | c.4260C>G p.S1420= (on ENST00000411696 / NM_001379660.1; = p.S1220= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 52/445 reads (12%) | called by muse, mutect2, varscan2
- ZNF764 | c.720C>T p.F240= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as rs1283459041; called by muse, mutect2, varscan2
- AC005863.1 | n.418A>T | RNA (SNP) | VAF 44/368 reads (12%) | called by muse, mutect2, varscan2
- AC020907.6 | c.-566C>T | 5'UTR (SNP) | VAF 44/344 reads (13%) | catalogued as rs778122130; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9725G>A | Intron (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- ACR | c.565+62G>A | Intron (SNP) | VAF 25/390 reads (6%) | catalogued as rs1455941310; called by muse, mutect2
- AL353804.7 | chrX:73846484 del TTATCAGCAACCCTTC | 5'Flank (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- ARMCX4 | c.1038+3782G>T | Intron (SNP) | VAF 40/114 reads (35%) | called by muse, mutect2, varscan2
- BOD1P2 | n.158C>A | RNA (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- C3orf52 | c.*259G>A | 3'UTR (SNP) | VAF 11/165 reads (7%) | catalogued as rs757559718; called by muse, mutect2
- CFAP46 | c.966+198G>A | Intron (SNP) | VAF 17/161 reads (11%) | catalogued as rs371257846, COSV63950141; called by muse, mutect2, varscan2
- DENND1B | c.83-20674del | Intron (DEL) | VAF 40/217 reads (18%) | called by mutect2, pindel, varscan2
- DOK3 | c.-22G>A | 5'UTR (SNP) | VAF 10/70 reads (14%) | catalogued as rs142992498; called by muse, mutect2, varscan2
- DYNC1H1 | c.13006+10A>T | Intron (SNP) | VAF 19/284 reads (7%) | called by muse, mutect2
- GUSBP4 | n.288C>T | RNA (SNP) | VAF 24/655 reads (4%) | called by muse, mutect2
- JAK3 | c.-13-13C>T | Intron (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2
- LINC00299 | n.2124G>A | RNA (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- LRRC37B | c.2124-3941C>T | Intron (SNP) | VAF 40/229 reads (17%) | called by muse, mutect2, varscan2
- MACROD2 | c.859+717C>T | Intron (SNP) | VAF 14/137 reads (10%) | catalogued as rs781039124, COSV53955820; called by muse, mutect2, varscan2
- MIER1 | c.-31C>G | 5'UTR (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- MLIP | c.613-11529G>T | Intron (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- MMGT1 | chrX:135974688 G>C | 5'Flank (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- MRRFP1 | n.174T>C | RNA (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- NAA40 | c.-68G>A | 5'UTR (SNP) | VAF 45/322 reads (14%) | catalogued as rs1310459503; called by muse, mutect2, varscan2
- PLEC | c.675+432G>T | Intron (SNP) | VAF 21/705 reads (3%) | called by muse, mutect2
- PREX1 | c.4412-32C>T | Intron (SNP) | VAF 59/449 reads (13%) | catalogued as rs372436566; called by muse, mutect2, varscan2
- RRM2B | c.48+212G>T | Intron (SNP) | VAF 39/341 reads (11%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.2697T>G | RNA (SNP) | VAF 59/499 reads (12%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.2698G>T | RNA (SNP) | VAF 57/495 reads (12%) | called by muse, mutect2, varscan2
- TM2D3 | c.91+64G>C | Intron (SNP) | VAF 14/367 reads (4%) | catalogued as rs1401847201, COSV60107712; called by muse, mutect2
- TMPRSS3 | c.*119G>A | 3'UTR (SNP) | VAF 36/464 reads (8%) | catalogued as rs745429674; called by muse, mutect2
- XKR6 | c.765-77605C>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- ZMYND15 | c.1838-13T>C | Intron (SNP) | VAF 17/318 reads (5%) | called by muse, mutect2
